Gene-level copy-number profile of tumor specimen TCGA-L5-A43C-01A from TCGA case TCGA-L5-A43C, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 81.5 years (29,753 days).
Specimen TCGA-L5-A43C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.a5cddec3-a238-42d6-8e29-52341d6eed5c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A43C-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f2999c7-e919-4d70-99df-af4a8184c268

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21,272; copy number 2: 37,000; copy number 3: 377; copy number 4: 976; copy number 5: 20; copy number 7: 79; copy number 8: 26; copy number 9: 35; copy number 12: 4; copy number 15: 14; copy number 16: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A43C-01A-11D-A246-01): tumor purity 0.22, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,857,267–4,175,899, 8 genes, copy number 8: DFFB, C1orf174, LINC01134, LINC01346, LINC01345, LINC02780, AL805961.1, EEF1DP6.
- chr7:94,738,652–97,024,950, 38 genes, copy number 5–8: ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5.
- chr8:123,178,960–123,210,079, 1 gene, copy number 7 (within-gene range 3–7): FAM83A.
- chr8:123,181,638–132,111,159, 143 genes, copy number 7–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,851. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
